Gene-level copy-number profile of tumor specimen TCGA-HC-8266-01A from TCGA case TCGA-HC-8266, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.5 years (20,280 days).
Specimen TCGA-HC-8266-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.0b0f504a-8615-4917-afce-69ca18de3b87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-8266-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e66cc1c3-bef3-44d1-949e-3e4e13ddbc9d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,199; copy number 2: 42,145; copy number 3: 3,649; copy number 5: 221; copy number 6: 1,537; copy number 7: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-8266-01A-11D-2259-01): tumor purity 0.25, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,827 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:27,063,996–29,064,764, 53 genes, copy number 5 (within-gene range 1–5): AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3, AC021678.1, AC021678.3, AC021678.2, RPL5P22, PNOC, ZNF395, FBXO16, AC025871.3, AC025871.2, RNU6-178P, AC025871.1, FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1.
- chr8:37,326,575–145,066,685, 1,704 genes, copy number 5–7 (broad region; genes not listed).
- chr17:29,390,363–29,551,903, 1 gene, copy number 6 (within-gene range 2–6): TAOK1.
- chr17:29,445,300–30,831,318, 69 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,819. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
